Somatic mutation profile of tumor specimen TARGET-10-PATGVX-09A (aliquot TARGET-10-PATGVX-09A-01D) from TARGET case TARGET-10-PATGVX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,668 days).
Specimen TARGET-10-PATGVX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 100f3c97-930f-4821-a106-696d0c4df3ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATGVX-10A (Blood Derived Normal), aliquot TARGET-10-PATGVX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2bf2b00-1e70-4532-9bd2-14ed00b3abb9

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 44/111 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AK8 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as rs946535640; called by muse, mutect2
- IL1F10 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.709); catalogued as rs764152714, COSV61750911; called by mutect2, varscan2
- MAP1B | c.6277C>T p.P2093S | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV57104456; called by muse, mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, varscan2
- OR5M11 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs778688024, COSV73141978; called by muse, mutect2, varscan2
- PLCB3 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54191452; called by muse, mutect2, varscan2
- PXDNL | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs558871034, COSV62496125; called by muse, mutect2, varscan2
- SNAP25 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs765666793, COSV54771068; called by muse, mutect2, varscan2
- TMEM182 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV68425387; called by muse, mutect2, varscan2
- ABHD15 | c.706_707insTGTACTGGCCCGA p.E236Vfs*87 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel
- USP9X | c.601dup p.Q201Pfs*4 | Frame Shift Ins (INS) | VAF 69/132 reads (52%) | called by mutect2, pindel, varscan2
- MN1 | c.1905G>A p.P635= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- OSCP1 | c.585C>T p.N195= (on ENST00000356637 / NM_001330493.1; = p.N185= on NM_145047.5) | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs369435790; called by muse, mutect2, varscan2
- TECTA | c.504C>T p.A168= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs1302036088; called by muse, mutect2, varscan2
- AC116366.2 | c.-637-16051_-637-16050insT | Intron (INS) | VAF 16/45 reads (36%) | called by mutect2, pindel
- FAP | c.1403-125del | Intron (DEL) | VAF 9/18 reads (50%) | catalogued as rs1301375922; called by mutect2, varscan2
